Somatic mutation profile of tumor specimen 0DJO5G from CCDI case PBBXGB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.3 years (2,659 days).
Specimen 0DJO5G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 199e3c40-dd80-4808-8722-8b7716a78f0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eeebabf-4455-42a1-998e-abf8647b52ac

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 1, 3'UTR 1, 5'Flank 1, Splice Site 1, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP5M1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 65/776 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1465738528; called by muse, mutect2
- APBA1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 110/709 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs140108483; called by muse, mutect2, varscan2
- BMPER | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 223/1032 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as rs767323516, COSV51818802; called by muse, mutect2, varscan2
- AHNAK2 | c.10853G>T p.G3618V | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSAD | c.966+1del p.X322_splice (on ENST00000444623 / NM_001244705.2; = p.X349_splice on NM_015989.5) | Splice Site (DEL) | VAF 122/423 reads (29%) | called by mutect2, varscan2
- IER5L | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); called by muse, mutect2
- MED1 | c.1328G>T p.C443F | Missense Mutation (SNP) | VAF 143/838 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- MICALL1 | c.1991A>G p.H664R | Missense Mutation (SNP) | VAF 27/812 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- MYO1F | c.1524+7C>T | Splice Region (SNP) | VAF 53/595 reads (9%) | called by muse, mutect2
- NOL4L | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 29/939 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCSK5 | c.5065T>C p.C1689R | Missense Mutation (SNP) | VAF 192/861 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SSC5D | c.4505G>T p.G1502V | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- TTLL6 | c.320A>T p.K107M | Missense Mutation (SNP) | VAF 84/1090 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF394 | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.019); called by muse, mutect2
- TNNI3 | c.540C>T p.D180= | Silent (SNP) | VAF 28/937 reads (3%) | called by muse, mutect2
- C3orf33 | c.*41A>T | 3'UTR (SNP) | VAF 32/220 reads (15%) | called by muse, mutect2, varscan2
- H2BC15 | chr6:27838372 G>A | 5'Flank (SNP) | VAF 33/262 reads (13%) | catalogued as rs775122572; called by muse, mutect2, varscan2
- SLC11A1 | c.1388+40C>T | Intron (SNP) | VAF 22/202 reads (11%) | called by muse, mutect2, varscan2
